Somatic mutation profile of tumor specimen TCGA-HC-7233-01A (aliquot TCGA-HC-7233-01A-11D-2114-08) from TCGA case TCGA-HC-7233, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-HC-7233-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9393fe7c-20f4-4c2a-a5a3-3d4514ab20af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7233-10A (Blood Derived Normal), aliquot TCGA-HC-7233-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf09ad13-10d7-4d7e-bc6e-4c739ceb89d0

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV51844801; called by muse, mutect2, varscan2
- CSMD3 | c.8122C>T p.R2708* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs773340701, COSV52214384; called by muse, mutect2, varscan2
- CSTF3 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs1416024472, COSV60612195; called by muse, mutect2, varscan2
- ERAP2 | c.2204A>T p.D735V | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV65940124; called by muse, mutect2
- GALNT10 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as rs1252215886, COSV51728382; called by muse, mutect2, varscan2
- HUS1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as rs1408682972, COSV51839788; called by muse, mutect2, varscan2
- MICU1 | c.1346A>G p.K449R (on ENST00000361114 / NM_001195518.2; = p.K455R on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.348); catalogued as COSV63145569; called by muse, mutect2, varscan2
- MYCBPAP | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60408937; called by muse, mutect2, varscan2
- NDST4 | c.450A>C p.L150F | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV52124113, COSV52126172; called by muse, mutect2
- NEUROG1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs894958768; called by muse, mutect2, varscan2
- NMS | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs750562734, COSV65258833; called by muse, mutect2
- PCDH18 | c.2630A>T p.D877V | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV61269414; called by muse, mutect2, varscan2
- PEDS1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV59013067; called by muse, mutect2, varscan2
- PHLDB1 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61879505; called by muse, mutect2, varscan2
- SOX12 | c.188C>G p.P63R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258939; called by muse, mutect2, varscan2
- SYNGAP1 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.626); catalogued as rs557096495, COSV53381373; ClinVar: uncertain significance; called by muse, varscan2
- TRAF2 | c.128G>T p.R43M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56038620; called by muse, mutect2, varscan2
- TRAF2 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56038656; called by muse, mutect2, varscan2
- TRIM36 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56690964; called by muse, mutect2, varscan2
- ZSCAN1 | c.879G>T p.Q293H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV56605545; called by muse, mutect2, varscan2
- KMT2C | c.390-1_391del p.X130_splice | Splice Site (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ZRANB1 | c.1226_1227del p.K409Rfs*10 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- ANK2 | c.11487C>T p.P3829= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs777600064, COSV52168212; called by mutect2, varscan2
- AOC1 | c.987C>T p.R329= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs546583289, COSV62869326; called by muse, mutect2, varscan2
- GPRC5A | c.771G>A p.L257= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV50007484; called by muse, mutect2, varscan2
- LYAR | c.321T>A p.V107= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV58643129; called by muse, mutect2, varscan2
- PCDHB2 | c.909G>T p.L303= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV50582870; called by muse, mutect2, varscan2
- RBL2 | c.729T>C p.C243= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV50880127; called by muse, mutect2, varscan2
- WFS1 | c.909G>A p.L303= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs758091097, COSV56989729; called by muse, mutect2, varscan2
